Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A27I, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A27I-01A (Primary Tumor).

ICD-0-3

Carcinoma, infiltrating lobular, NOS

Site: breast, NOS C50.9

8520/3

lw 5/19/11

page 1 / 1

copy No. 4

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: Multiple organ resection - right breast with axillary tissues

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: up to 8 working days

Clinical diagnosis: Cancer of the right breast.

Examination performed on:

Macroscopic description:

Right breast sized 19.3 x 14.2 x 5.8 cm removed along with axillary tissues sized 10 x 6 x 3 cm and a skin flap of 16.2 x 6.8 cm. Tumour sized 1.7 x 1.2 x 1.5 cm on the border of outer quadrants, located 6.3 cm from the upper boundary, 0.3 cm from the base and 1.2 cm from the skin.

Microscopic description:

Carcinoma lobulare invasivum (classical type) multifocale - NHG2 (3 + 2 + 1; 0 mitoses/10 HPF, visual area diameter 0.55 mm). Infiltratio carcinomatosa mamillae.

Parenchymal atrophy showing in the glandular tissue.

AXILLARY LYMPH NODES

Metastases carcinomatosa in lymphonodis (NO IV/X).

Histopathological Diagnosis:

Carcinoma lobulare invasivum multifocale mammae dextrae. Invasive multifocal lobular carcinoma of the right breast.

Metastases carcinomatosa in lymphonodis axillae (NO IV/X). Cancer metastases in axillary lymph nodes. (NHG2, pT1c, pN2a).

Compliance validated by:

Source: NCI Genomic Data Commons file ec93ca2d-d2e7-414d-b26a-4f779ab10480 (TCGA-D8-A27I.FAB622C2-3E45-4E72-AA36-9530BB830993.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).